Somatic mutation profile of tumor specimen C3L-04339-01 (aliquot CPT0258090006) from CPTAC case C3L-04339, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.4 years (23,161 days).
Specimen C3L-04339-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1f6cfd8-3daf-44cc-912c-194f3e82ece0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04339-31 (Blood Derived Normal), aliquot CPT0258190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b88744e-b833-4a8d-b68b-bbd0c208557a

The open-access MAF lists 59 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 13, Intron 5, 3'UTR 3, RNA 2, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 18/230 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.584T>A p.I195N | Missense Mutation (SNP) | VAF 67/419 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACVRL1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.081); catalogued as rs755786527, COSV66361343; called by muse, mutect2, varscan2
- AMER3 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs368379439; called by muse, mutect2, varscan2
- ANGPT2 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs773239022; called by muse, mutect2, varscan2
- B3GNT6 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1555027846, COSV62829466; called by muse, varscan2
- BCAS1 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as rs1027786237, COSV65086011; called by muse, mutect2, varscan2
- CYP3A7 | c.562T>A p.S188T | Missense Mutation (SNP) | VAF 74/576 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs760742049; called by muse, mutect2, varscan2
- EXD3 | c.2524G>A p.G842S | Missense Mutation (SNP) | VAF 39/367 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs775413905, COSV100574042; called by muse, mutect2, varscan2
- EZHIP | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs782524965, COSV100539730; called by muse, mutect2, varscan2
- ITIH2 | c.1234T>A p.S412T | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64432149; called by muse, mutect2
- KCNU1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs180964986, COSV67755904; called by muse, mutect2
- STAG2 | c.3173C>A p.S1058* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as COSV54350699, COSV54364076; called by muse, mutect2, varscan2
- SYT7 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.68); catalogued as rs200881282, COSV55657728; called by muse, mutect2, varscan2
- UNKL | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 95/540 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1026870029, COSV57019153, COSV57020875; called by muse, mutect2, varscan2
- ADGRG4 | c.5108C>T p.T1703I | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKR1C1 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CENPE | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 63/478 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CEP162 | c.1217T>G p.F406C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- DLC1 | c.3122C>T p.A1041V (on ENST00000276297 / NM_001348081.2; = p.A604V on NM_006094.5) | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- DNAH3 | c.11795A>T p.Y3932F | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2
- DNAH8 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GCC2 | c.4526C>A p.T1509N | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- IL36B | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- KCNC4 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRIF1 | c.1937_1938del p.T646Rfs*5 | Frame Shift Del (DEL) | VAF 27/255 reads (11%) | called by mutect2, pindel, varscan2
- MYH8 | c.2291C>A p.T764N | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MYO6 | c.2527G>A p.V843M | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.568); called by muse, mutect2
- OR4K2 | c.110C>A p.A37E | Missense Mutation (SNP) | VAF 17/534 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2
- OR6N1 | c.865A>T p.I289F | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PCNX3 | c.2789T>G p.L930R | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PIK3CA | c.29_52del p.L10_P17del | In Frame Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- RGS22 | c.3721C>G p.L1241V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPUSD2 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TFEB | c.892C>G p.L298V | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.1); called by muse, mutect2
- XBP1 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ADAM28 | c.615C>T p.Y205= | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- CSMD1 | c.5361C>T p.N1787= (on ENST00000520002; = p.N1786= on NM_033225.6) | Silent (SNP) | VAF 51/420 reads (12%) | catalogued as rs34443453; called by muse, mutect2, varscan2
- GEMIN4 | c.1389C>T p.D463= | Silent (SNP) | VAF 46/362 reads (13%) | catalogued as rs751606537; called by muse, mutect2, varscan2
- ICAM4 | c.738C>T p.I246= | Silent (SNP) | VAF 73/517 reads (14%) | called by muse, mutect2, varscan2
- KCNK1 | c.60C>A p.A20= | Silent (SNP) | VAF 38/342 reads (11%) | called by muse, mutect2, varscan2
- MPZL2 | c.348C>T p.D116= | Silent (SNP) | VAF 107/519 reads (21%) | catalogued as rs374615940; called by muse, mutect2, varscan2
- PRR23A | c.495G>A p.P165= | Silent (SNP) | VAF 53/372 reads (14%) | catalogued as rs751378737; called by muse, mutect2, varscan2
- SH3GL3 | c.651G>A p.V217= | Silent (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- ST6GALNAC3 | c.450T>C p.T150= | Silent (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- TRADD | c.24C>T p.H8= | Silent (SNP) | VAF 131/764 reads (17%) | catalogued as rs199806094; called by muse, mutect2, varscan2
- TRPM3 | c.3528G>A p.P1176= (on ENST00000357533 / NM_001366142.2; = p.P1031= on NM_020952.6) | Silent (SNP) | VAF 40/277 reads (14%) | catalogued as rs142146497, COSV62585179; called by muse, mutect2, varscan2
- USP50 | c.594C>T p.I198= (on ENST00000616326; = p.I189= on NM_203494.5) | Silent (SNP) | VAF 44/288 reads (15%) | catalogued as rs559577672, COSV73214076; called by muse, mutect2, varscan2
- WASHC2A | c.3297C>T p.A1099= | Silent (SNP) | VAF 143/1000 reads (14%) | catalogued as rs990305170; called by muse, mutect2, varscan2
- CCL4L2 | c.192-50C>A | Intron (SNP) | VAF 29/522 reads (6%) | called by muse, mutect2
- CHRNA4 | c.274-16G>A | Intron (SNP) | VAF 15/98 reads (15%) | catalogued as rs201948072; called by muse, mutect2
- CLUHP11 | n.783C>G | RNA (SNP) | VAF 38/213 reads (18%) | called by muse, mutect2, varscan2
- DDX27 | c.1887+41G>T | Intron (SNP) | VAF 62/449 reads (14%) | called by muse, mutect2, varscan2
- FUS | c.190+121C>A | Intron (SNP) | VAF 14/85 reads (16%) | called by muse, varscan2
- HMG20B | c.*331A>G | 3'UTR (SNP) | VAF 38/207 reads (18%) | called by muse, mutect2, varscan2
- MIDN | c.*2A>G | 3'UTR (SNP) | VAF 68/422 reads (16%) | catalogued as rs757629749; called by muse, mutect2, varscan2
- SCN2B | c.*26G>A | 3'UTR (SNP) | VAF 118/556 reads (21%) | catalogued as rs368267712; called by muse, mutect2, varscan2
- SSPOP | n.5528G>T | RNA (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- TTN | c.34265-5080C>T | Intron (SNP) | VAF 24/269 reads (9%) | catalogued as rs555029471, COSV59903942; called by muse, mutect2
